Surgical pathology report (de-identified scan), TCGA case TCGA-06-6697, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6697-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

Surgical Pathology Report

TCGA-06-6697

[REDACTED]

CLINICAL HISTORY

Right temporal lobe brain mass

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain tumor, biopsy

B: Brain tumor, biopsy

C: Brain, excision biopsy

D: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. D. Brain, right temporal tumor, resection: Malignant neoplasm consistent with gliosarcoma (WHO Grade IV) (see comment).

COMMENT

Sections show a mitotically active tumor composed of strongly GFAP and S100

positive areas with cells resembling neoplastic astrocytes and other more

epithelioid cells resembling meningioma. Microvascular proliferation is

present however, is not a dominant feature of the tumor vasculature. A distinct area shows more spindle shaped cells which are mostly GFAP and S100

negative and CD34 and reticulin positive. Vimentin is diffusely positive. EMA

shows scattered weak positivity. Pan-keratin is negative. The Ki-67 labeling

index is up to approximately 30%. Positive and negative controls show appropriate immunoreactivity.

This is an unusual tumor. Considering the present histological findings and

clinical findings reviewed at our recent [REDACTED] the lesion

appears to be more consistent with gliosarcoma. A recent study found that

[page 2 of 3]
gliosarcomas resembling meningiomas (surgically and macroscopically) may be associated with prolonged patient survival compared to classical gliosarcomas.

INTRA-OPERATIVE CONSULTATION

A. Brain tumor, biopsy: Recurrent malignant neoplasm (favor glioma). Frozen section performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

B. Brain tumor, biopsy: Recurrent malignant neoplasm (favor glioma). Frozen section performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A. Brain tumor, biopsy:
CONTAINER LABEL: Brain tumor
FIXATIVE: Fresh. NO. PIECES: 1 fragment of tan-pink, glistening, soft tissue.

SIZE/VOL: 1.5 x 1.3 x 1.0 cm. CASSETTES: 2, NS as follows: A1- frozen section remnant, A2- remaining tissue.

B. Brain tumor, biopsy:
CONTAINER LABEL: "B" and patient's name
FIXATIVE: Fresh. NO. PIECES: multiple fragments of tan-pink, glistening, soft tissue. SIZE/VOL: 1.2 x 0.8 x 0.3 cm. CASSETTES: 1, NS (frozen section remnant). L, [REDACTED]

C. Brain, excision biopsy:
CONTAINER LABEL: brain
FIXATIVE: Formalin. NO. PIECES: few SIZE/VOL: 1 x 1 x 0.5 cm. CASSETTES: 1, [REDACTED]

D. Brain, excision biopsy:
CONTAINER LABEL: brain
FIXATIVE: Formalin. NO. PIECES: few fragments of pink-tan glistening granular soft tissue. SIZE/VOL: 3 x 1 x 0.8 cm. CASSETTES: 3, [REDACTED]

[page 3 of 3]
ICD-9(s):
191.9 191.9

Histo Data

Part A: Brain tumor, biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	

Part B: Brain tumor, biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	

Part C: Brain, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	

Part D: Brain, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
CD34-DA x 1	3	[REDACTED]	
EMA-DA x 1	3	[REDACTED]	
mGFAP-DA x 1	3	[REDACTED]	
H/E x 1	3	[REDACTED]	
KeratinSu x 1	3	[REDACTED]	
MIB1-DA x 1	3	[REDACTED]	
Rct 1 H/E x 1	3	[REDACTED]	
Retic x 1	3	[REDACTED]	
S100-DA x 1	3	[REDACTED]	
Vim-DA x 1	3	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 93b9cf61-a3c5-42e7-b495-5a21564ec908 (TCGA-06-6697.6D372549-29B6-4A4F-B8F5-D9267B1B91D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).